Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A55Z, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A55Z-01A (Primary Tumor).

[page 1 of 2]
----- SURGICAL PATHOLOGY -----

MEDICAL RECORD	SURGICAL PATHOLOGY

PATHOLOGY REPORT	

RIGHT RENAL MASS

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

right renal mass

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

right renal mass

1CD-0-3

carcinoma, papillary renal cell 8260/3

Site: Kidney, nos C64.9

hw

11/25/12

=====

PATHOLOGY REPORT

GROSS DESCRIPTION:

Received fresh is a 112.3 g, 5.8 x 5.3 x 4.7 cm partial nephrectomy specime displaying moderate amounts of attached peinephric fat. The renal resection margin is tan-red and scabrous. The capsular margin is tan-white and smooth. The renal resection margin is inked blue, and the capsular margin is inked black. The specimen is serially sectioned to reveal a 5.2 x 3.9 x 3.5 cm, tan-yellow to red, to orange, variegated, well-circumscribed mass that is 0.3 cm from the renal resection margin, and less than 0.1 cm from the capsular resection margin. Grossly the mass is confined to the renal capsule. The rim of uninvolved renal parenchyma is tan-brown and unremarkable. Sectioning through the attached fat does not reveal any obvious lymph nodes. No adrenal gland is identified.

Representative sections are submitted as follows: 1-5- mass to renal resection margin; 6-8- mass to capsule resection margin.

MICROSCOPIC EXAM

FINAL DIAGNOSIS:

RIGHT RENAL MASS, RESECTION:

PROCEDURE: PARTIAL SPARING NEPHRECTOMY.

LATERALITY: RIGHT.

TUMOR SITE: NOT PROVIDED.

TUMOR SIZE: 5.2 CM

TUMOR FOCALITY: SINGLE LESION.

MACROSCOPIC EXTENT OF TUMOR: CONFINED TO PARENCHYMA.

HISTOLOGIC TYPE: PAPILLARY RENAL CELL CARCINOMA.

TUMOR NECROSIS: NOT IDENTIFIED.

HISTOLOGIC GRADE: G2.

MICROSCOPIC TUMOR EXTENSION: CONFINED TO KIDNEY.

SURGICAL MARGINS

GEROTA'S FASCIAL MARGIN: FREE OF TUMOR.

RENAL PARENCHYMAL RESECTION MARGIN: FREE OF TUMOR.

PATHOLOGICAL STAGE (pTNM):

pT1b.

[page 2 of 2]
NONNEOPLASTIC KIDNEY:

- FOCAL GLOMERULOSCLEROSIS.
- ARTERIO- AND ARTERIOLONEPHROSCLEROSIS.
- INTERSTITIAL FIBROSIS AND CHRONIC INFLAMMATION SEEN.

COMMENT: CONCURS WITH NEW MALIGNANCY. IMAGES ARE
AVAILABLE IN UROLOGY NOTIFIED

MD

(End of report)

Significant Discrepancy		☒
Primary Discrepancy		☒
History of Malignancy		☒
Qual/Synch orous Primary Tumor		☒
Reviewer Initials	Date Re-reviewed 11/21/2012	

Source: NCI Genomic Data Commons file 58a0b6b9-5c83-42e8-906b-63c44705226f (TCGA-MH-A55Z.5914C86E-637F-496A-B416-E9E750527042.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).